Somatic mutation profile of tumor specimen TCGA-TM-A84S-01A (aliquot TCGA-TM-A84S-01A-11D-A36O-08) from TCGA case TCGA-TM-A84S, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Oligodendroglioma, anaplastic; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 36.8 years (13,424 days).
Specimen TCGA-TM-A84S-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3f90c6db-5669-4f70-9d4c-3a94f8c4ce7b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-TM-A84S-10A (Blood Derived Normal), aliquot TCGA-TM-A84S-10A-01D-A367-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/867c46cf-990a-4e39-8609-c4c5bfef5c3e

The open-access MAF lists 15 somatic variants for this specimen: 11 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Silent 3, Nonsense Mutation 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 33/88 reads (38%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- PIK3CA | c.3127A>G p.M1043V | Missense Mutation (SNP) | VAF 6/58 reads (10%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.026); catalogued as rs1057519936, COSV55879858, COSV55890961; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- AARS1 | c.1699C>G p.Q567E | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs992919450, COSV99933188; called by muse, mutect2, varscan2
- ADAMTS20 | c.329G>A p.G110E | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs905321350, COSV101238889; called by muse, mutect2, varscan2
- ARHGAP9 | c.2078G>A p.C693Y (on ENST00000393797 / NM_001319850.2; = p.C674Y on NM_032496.4) | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as COSV99953664; called by muse, mutect2, varscan2
- ARID1A | c.4288C>T p.Q1430* | Nonsense Mutation (SNP) | VAF 10/50 reads (20%) | catalogued as COSV61382655; called by muse, mutect2, varscan2
- FKBP8 | c.253G>A p.A85T | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT tolerated (0.6); PolyPhen benign (0.165); catalogued as rs374983500; called by muse, mutect2, varscan2
- MYO19 | c.1475G>A p.R492H | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs757720951; called by muse, mutect2, varscan2
- PPIP5K1 | c.3656G>A p.G1219E (on ENST00000396923; = p.G1194E on NM_014659.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 34/96 reads (35%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as COSV100288066; called by muse, mutect2, varscan2
- TLK1 | c.1478G>C p.W493S | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100687335; called by muse, mutect2, varscan2
- ZNF18 | c.1130C>A p.P377H | Missense Mutation (SNP) | VAF 33/97 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.41); catalogued as COSV100503034; called by muse, mutect2, varscan2
- CTSV | c.123C>G p.G41= | Silent (SNP) | VAF 7/88 reads (8%) | catalogued as COSV52345517, COSV99414298; called by muse, mutect2
- NRDE2 | c.123A>G p.Q41= | Silent (SNP) | VAF 52/157 reads (33%) | catalogued as rs1426677851, COSV100583263; called by muse, mutect2, varscan2
- SLC45A2 | c.1101C>T p.V367= | Silent (SNP) | VAF 19/128 reads (15%) | catalogued as rs771634345, COSV56869515, COSV56871929; called by muse, mutect2, varscan2
- MGAT4B | c.98-20G>A | Intron (SNP) | VAF 18/92 reads (20%) | catalogued as rs548114496, COSV99482033; called by muse, mutect2, varscan2
